Gene-level copy-number profile of tumor specimen ALCH-AF1T-TTP1-A from ALCHEMIST case ALCH-AF1T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,974 days).
Specimen ALCH-AF1T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 81c7ae46-0bae-46ba-a4c0-5cc3ee23a2aa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF1T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/cddfd03d-3c47-4f55-9e63-255436ffc66f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 1,623; copy number 2: 55,726; copy number 3: 891; copy number 4: 55; copy number 5: 11; copy number 6: 2; copy number 7: 1; copy number 10: 1; copy number 15: 2; copy number 42: 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:23,616,499–23,617,987, 1 gene (within-gene range 0–2): AC011239.2.
- chr2:72,916,260–72,936,071, 2 genes: EMX1, AC012366.1.
- chr2:89,252,211–89,310,144, 8 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr3:9,793,082–9,855,138, 4 genes (within-gene range 0–1): ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3.
- chr3:46,835,111–46,903,799, 2 genes: MYL3, PTH1R.
- chr3:50,558,025–50,571,027, 1 gene (within-gene range 0–2): C3orf18.
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.
- chr5:139,647,299–139,683,882, 2 genes (within-gene range 0–2): CXXC5, CXXC5-AS1.
- chr5:176,880,869–176,899,346, 1 gene (within-gene range 0–1): HK3.
- chr8:144,098,633–144,108,124, 2 genes (within-gene range 0–4): SHARPIN, MAF1.
- chr9:93,951,627–93,955,355, 1 gene: BARX1.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–1): MIR601.
- chr9:130,933,851–130,945,520, 1 gene (within-gene range 0–1): AL161733.1.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr11:130,159,782–130,210,362, 1 gene: ST14.
- chr12:66,767–182,399, 5 genes (within-gene range 0–1): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3.
- chr15:25,241,746–25,257,027, 7 genes (within-gene range 0–2): SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:41,825,099–41,899,528, 8 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:76,976,915–77,037,475, 3 genes: RN7SL278P, KRT8P23, PSTPIP1.
- chr15:89,335,053–89,360,377, 2 genes: AC124068.2, AC133637.1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:29,009,799–29,011,009, 1 gene (within-gene range 0–2): AC024619.2.
- chr19:6,467,207–6,482,557, 2 genes (within-gene range 0–2): DENND1C, AC010503.4.
- chr19:35,106,510–35,142,451, 4 genes (within-gene range 0–2): AC020907.6, FXYD3, MIR6887, LGI4.
- chr20:64,049,836–64,072,347, 2 genes: TCEA2, AL355803.1.
- chr22:19,130,279–19,150,292, 3 genes: ESS2, TSSK2, GSC2.
- chr22:42,132,543–42,132,998, 1 gene (within-gene range 0–3): AC254562.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:144,049,079–144,063,965, 3 genes, copy number 7–15: SMPD5, OPLAH, MIR6846.
- chr9:130,892,707–130,896,812, 1 gene, copy number 5: QRFP.
- chr10:44,712–46,884, 1 gene, copy number 6: AL713922.1.
- chr16:29,380,242–29,380,345, 1 gene, copy number 10: AC025279.3.
- chr16:29,475,064–29,505,999, 3 genes, copy number 5–6: AC133555.2, AC133555.1, NPIPB12.
- chr17:49,598,884–49,678,163, 1 gene, copy number 5: SPOP.
- chr22:21,300,990–21,325,042, 2 genes, copy number 5 (within-gene range 2–5): FAM230H, AP000552.2.
- chr22:21,379,382–21,396,590, 5 genes, copy number 5: Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.
- chr22:21,466,423–21,471,269, 1 gene, copy number 42: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 1,623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
